Somatic mutation profile of tumor specimen C3N-01364-02 (aliquot CPT0093450009) from CPTAC case C3N-01364, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 34.2 years (12,483 days).
Specimen C3N-01364-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5463999d-95e4-469f-8140-eb3ce6652f32.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01364-31 (Blood Derived Normal), aliquot CPT0093490002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5c041afc-2a29-4d69-be2b-668bb67fa44f

The open-access MAF lists 25 somatic variants for this specimen: 18 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 6, Nonsense Mutation 3, Intron 1, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 121/481 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- MEN1 | c.927+1G>C p.X309_splice | Splice Site (SNP) | VAF 117/322 reads (36%) | catalogued as rs398124437, CS054205, CS991449, COSV53640573, COSV53643674; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AEBP2 | c.1300G>C p.V434L | Missense Mutation (SNP) | VAF 19/115 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.97); catalogued as COSV56861883; called by muse, mutect2, varscan2
- ALDH16A1 | c.986G>A p.R329Q | Missense Mutation (SNP) | VAF 30/157 reads (19%) | SIFT tolerated (0.41); PolyPhen benign (0.009); catalogued as rs373691925; called by muse, mutect2, varscan2
- C11orf80 | c.1468C>T p.R490C | Missense Mutation (SNP) | VAF 15/167 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as rs771347098, COSV60929254, COSV60931469; called by muse, mutect2, varscan2
- CBX6 | c.440G>A p.R147H | Missense Mutation (SNP) | VAF 52/185 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53321219; called by muse, mutect2, varscan2
- NELFB | c.622G>A p.E208K | Missense Mutation (SNP) | VAF 71/448 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); catalogued as rs762179684, COSV58026077; called by muse, mutect2, varscan2
- PCLO | c.9148C>T p.R3050* | Nonsense Mutation (SNP) | VAF 44/159 reads (28%) | catalogued as rs1408845429, COSV61652203; called by muse, mutect2, varscan2
- TBC1D4 | c.2784G>T p.W928C | Missense Mutation (SNP) | VAF 132/389 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1398695660; called by mutect2, varscan2
- CYB561A3 | c.228dup p.L77Tfs*100 | Frame Shift Ins (INS) | VAF 110/302 reads (36%) | called by mutect2, pindel, varscan2
- FCN1 | c.840C>G p.Y280* | Nonsense Mutation (SNP) | VAF 93/469 reads (20%) | called by muse, mutect2, varscan2
- IRAK4 | c.1331G>C p.R444T | Missense Mutation (SNP) | VAF 81/282 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- KCNA1 | c.1309T>A p.S437T | Missense Mutation (SNP) | VAF 81/283 reads (29%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- OPA3 | c.271A>T p.I91F | Missense Mutation (SNP) | VAF 91/303 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.536); called by muse, mutect2, varscan2
- PPP1R13B | c.1841T>G p.L614* | Nonsense Mutation (SNP) | VAF 7/16 reads (44%) | called by muse, varscan2
- RABEP1 | c.1426A>G p.I476V | Missense Mutation (SNP) | VAF 99/275 reads (36%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- SLIT3 | c.1053C>A p.F351L | Missense Mutation (SNP) | VAF 76/260 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- VARS1 | c.2894G>A p.G965E | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- ARFRP1 | c.369G>A p.A123= | Silent (SNP) | VAF 37/184 reads (20%) | catalogued as rs1224824107, COSV53927624; called by muse, varscan2
- CYTIP | c.789G>C p.T263= | Silent (SNP) | VAF 80/294 reads (27%) | catalogued as rs748797841; called by muse, mutect2, varscan2
- HSD17B1 | c.273C>T p.N91= | Silent (SNP) | VAF 66/189 reads (35%) | catalogued as COSV56797517; called by muse, mutect2, varscan2
- IKZF2 | c.324G>A p.P108= | Silent (SNP) | VAF 110/485 reads (23%) | catalogued as rs868111109, COSV59583799; called by muse, mutect2, varscan2
- NACC2 | c.108C>G p.V36= | Silent (SNP) | VAF 204/603 reads (34%) | called by muse, mutect2, varscan2
- PHKA1 | c.807A>G p.A269= | Silent (SNP) | VAF 25/379 reads (7%) | called by muse, mutect2
- ST3GAL3 | c.348-14991C>A | Intron (SNP) | VAF 37/212 reads (17%) | called by muse, mutect2, varscan2
